Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5374, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5374-01A (Primary Tumor).

[page 1 of 3]
PATIENT HISTORY:

Metastases -squamous cancer left neck. Primary unknown.

PRE-OP DIAGNOSIS: Cancer of pharynx.

POST-OP DIAGNOSIS: Same.

CEDEURE: Biopsy-tonsillectomy.

ADDENDA:

Addendum

In situ hybridization for Human Papilloma Virus is positive.

My siestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: BASE OF TONGUE, LEFT, BIOPSY

A. SQUAMOUS MUCOSA WITH LYMPHOID TISSUE.

B. NO TUMOR SEEN.

PART 2: TONSIL, LEFT, TONSILLECTOMY

INVASIVE SQUAMOUS CELL CARCINOMA, AT LEAST 2.1 CM, MODERATELY TO POORLY

DIFFERENTIATED, EXTENDING TO EXCISION MARGIN (see comment).

PART 3: TONSIL, RIGHT, TONSILLECTOMY

A. HYPERPLASTIC TONSIL.

NO TUMOR SEEN.

HPV in situ hybridization is ordered and result will be reported in an addendum. According to the history, the greatest portion of this tumor was banked by Dr. per prior to receiving the specimen in pathology.

[page 2 of 3]
My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in 3 parts.

Part 1 is received fresh labeled with the patient's name, initials xxx and

"left tongue base". Received are multiple, pink, irregular soft, tissue fragments ranging in size from 0.2 to 0.7 cm in greatest dimension.

The specimen is entirely submitted for processing in a cassette labeled 1A. Part 2 is received fresh labeled with the patient's name, initials xxx and

"left tonsil". Received is a 3.1 X 2.2 X 1.5 cm tonsil covered by tan-white,

convoluted, squamous mucosa overlying tan- ivory, rubbery, tissue.

Specimen

is inked and serially sectioned and revealing a well-circumscribed, tan,

gritty, tumor measuring 2.1 x 2.0 x 1.4 cm and approaching the deep resection

margin by less than 0.1 cm. Greater portion of the tumor and specimen was

banked as per [REDACTED] - [REDACTED], prior to receipt in pathology

lab. Remaining tissue is entirely submitted in cassettes labeled:

2A - tumor in relationship to resection margin

2B - remaining deep resection margin.

Part 3 is received fresh labeled with the patient's name, initials xxx and

"right tonsil". Received is a 2 x 1.2 x 0.9 cm tonsil covered by tan-white,

convoluted, squamous mucosa overlying tan-pink, unremarkable, soft, tissue.

Specimen is inked and serially sectioned and reveals slightly lobulated,

possible tonsillar crypts. No definitive tumor is noted. Specimen is entirely

mitted in cassettes labeled 3A-3B.

[REDACTED]

opic examination substantiates the above diagnosis.

[REDACTED]

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined

by the [REDACTED], Department of Pathology, as required by the

[REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use.

[page 3 of 3]
This laboratory [REDACTED] certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: [REDACTED] se

Taken: [REDACTED] Received: [REDACTED]

Stain/c

HHE x 1 A

H&E x 1 A

Part 2:

Taken: [REDACTED] Received: [REDACTED]

Stain/c

IHPV x 1 A

IBNKNC x 2 A

H&E x 1 A

IISH x 1 A

H&E x 1 B

Part 3:

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A

[REDACTED] x 1 B

[REDACTED]

Source: NCI Genomic Data Commons file 078c71e3-f13c-418a-b817-6da074f2cab6 (TCGA-CN-5374.3F24C555-1E57-44F6-B11C-4DE7AD28E18B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).